TCGA case TCGA-BA-5153 — Head and Neck Squamous Cell Carcinoma (TCGA-HNSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Tonsil; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b3631718-9e0a-454c-bee1-8f36ebc509d8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 1,762 days (4.8 years).

Diagnoses (3)
1. Squamous cell carcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8070/3; ICD-10 code: C09.9; Tissue or organ of origin: Tonsil, NOS; Site of resection or biopsy: Head, face or neck, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 51.3 years (18,743 days); Year of diagnosis: 2005; AJCC staging edition: 6th; AJCC clinical T: T2; AJCC clinical N: N1; AJCC clinical M: M0; AJCC clinical stage: Stage III; AJCC pathologic T: T2; AJCC pathologic N: NX; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Lymph nodes tested: 0; Margin status: Involved; Perineural invasion present: No.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Adjuvant; Days to treatment start: 41 days; Days to treatment end: 91 days; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Treatment intent type: Palliative.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin.
   Treatment given: Treatment type: Radiation Therapy, NOS; Treatment intent type: Palliative; Course number: 2; Treatment anatomic sites: Distant Site.
   Treatment given: Treatment type: Ancillary Treatment; Therapeutic agents: Zoledronic Acid; Treatment intent type: Palliative.
2. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Pelvic bones, sacrum, coccyx and associated joints. Age at diagnosis: 55.5 years (20,265 days); Days to diagnosis: 1,522 days (4.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Distant Site, for progressive disease.
3. Metastasis of diagnosis 1 (Squamous cell carcinoma, NOS), site: Bones of skull and face and associated joints. Age at diagnosis: 55.7 years (20,359 days); Days to diagnosis: 1,616 days (4.4 years); Prior treatment: Yes.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease; Radiation Therapy, NOS, for progressive disease; Surgery, NOS to Distant Site, for progressive disease.

Follow-up (5 entries)
- Day 1,522 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Pelvic bones, sacrum, coccyx and associated joints; Days to recurrence: 1,522 days (4.2 years).
- Day 1,522 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Pelvic bones, sacrum, coccyx and associated joints; Days to progression: 1,522 days (4.2 years).
- Day 1,616 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Bones of skull and face and associated joints; Days to recurrence: 1,616 days (4.4 years).
- Day 1,616 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bones of skull and face and associated joints; Days to progression: 1,616 days (4.4 years).
- Days to follow up: 1,762 days (4.8 years); Disease response: With Tumor.

Exposures
- Alcohol history: No; Alcohol drinks per day: 0; Alcohol days per week: 0.
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BA-5153-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.6; Intermediate dimension: 0.6; Shortest dimension: 0.1.
  Slide TCGA-BA-5153-01A-01-BS1: Section location: Bottom; Percent tumor cells: 82; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 15.
  Slide TCGA-BA-5153-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
- Sample TCGA-BA-5153-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BA-5153-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Head and Neck; Histologic diagnosis: Head & Neck Squamous Cell Carcinoma; Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Lymph nodes examined: No; Lymph node neck dissection indicator: No; Margin status: Positive; Tobacco smoking history indicator: 1; Alcohol history documented: Yes; Alcohol consumption frequency: 0.
- Drug treatment 1: Regimen number: 2; Pharmaceutical therapy drug name: Xeloda.
- Drug treatment 2: Regimen number: 3; Therapy regimen: Progression.
- Drug treatment 3: Regimen number: 2; Pharmaceutical therapy drug name: Zometa.
- Follow-up form 1: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event surgery met: No; New tumor event site: Distant Metastasis; New tumor event site other: bone (skull).
- Follow-up form 2: New tumor event surgery: No; Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No; New tumor event site: Distant Metastasis; New tumor event site other: bone (hip); Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,762 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,762 days; disease-free interval: event (new tumor event after initially disease-free), 1,522 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,522 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BA-5153-01A-01D-1432-01): tumor purity 0.79, ploidy 2, whole-genome doublings 0.
